Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6AL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6AL-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY:

PROCEDURE DATE: RECEIVED DATE: REPORT DATE:

COPY TO: [REDACTED]

ICD-O-3
c6cf Adenocarcinoma, NOS 8140/3
path
Adenocarcinoma, NOS 8140/3
Site Prostate NOS C61.9
QW 01/16/13

Pre-Op Diagnosis
Malignant neoplasm of prostate
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Two parts

Container labeled [REDACTED] 1 - prostate" is a previously inked, previously sectioned moderately distorted prostate gland with attached bilateral seminal vesicles. The specimen is received after tissue harvest for genomic study and all measurements and weights are taken prior to tissue harvest on the intact specimen. Within the container are three tissue cassettes labeled
The prostate gland weights 55 grams in the intact fresh state and measures 5.2 x 4.0 x 3.8 cm. The outer surface is focally shaggy gray tan to pink. capsule. The urethra is 3.5 x 0.5 x 0.3 cm and is patent with evidence of compression by the lateral lobes. The cut surface shows multinodular rubbery gray tan to pink fibrotic cut surface. Noted in the left posterior lobe at a point approximately 0.9 cm from the apex is a poorly defined approximately 1.2 x 0.9 x 0.8 cm area of slight gray tan to pink induration which grossly extends approximately 0.1 cm from the nearest soft tissue margin. The remaining tissue is somewhat nodular rubbery gray tan to pink without additional discrete gross lesions. The seminal vesicles together measure 6.0 x 3.1 x 1.1 cm. These have lobulated tan pink outer surfaces with multicystic tan pink fibrotic cut surface. No gross mass lesions are identified. Representative sections are submitted as labeled as follows: A - radial apical (distal) margin, left; B - radial apical (distal) margin, right; C - shave vesical

[page 2 of 2]
(proximal) margin; D - left lateral lobe distal; E - right lateral lobe distal; F - left posterior lobe distal; G - right posterior lobe distal; H - left lateral lobe mid region; I - right lateral lobe mid region; J - left posterior lobe mid region; K - right posterior lobe mid region; L - left lateral lobe proximal region; M - right lateral lobe proximal region; N - left posterior lobe proximal region; O - right posterior lobe proximal region; P - origin of the seminal vesicles; Q - representative left seminal vesicle; R - representative right seminal vesicle.

Container labeled [REDACTED] 2 - bilateral pelvic lymph nodes" is 4.0 x 2.5 x 1.0 cm tan yellow fibroadipose tissue fragments which on palpation and sectioning reveal a few poorly defined pink yellow nodules up to 2.6 cm. The nodules are individually submitted in three cassettes.

Microscopic Description:

Reviewed are slides labeled [REDACTED]

Final Diagnosis

Prostate, radical prostatectomy:

Tumor characteristics:

Specimen integrity: Intact.

Histologic type: Adenocarcinoma.

Prostate size: 55 grams, 5.2 x 4.0 x 3.8 cm.

Tumor quantitation: Tumor involves less than 10% of total tissue volume.

Gleason grade:

Primary pattern: 3/5

Secondary pattern: 4/5

Total Gleason score: 7/10

Extraprostatic extension: No unequivocal extraprostatic extension identified.

Seminal vesicle involvement: Not identified.

Lymphovascular space invasion: No unequivocal lymphovascular space invasion identified.

Perineural invasion: Present, extensive.

High grade PIN: Present.

Treatment effect: Not identified/unknown.

Surgical Margin Status:

Surgical margins appear free of malignancy in sections examined.

Tumor extends to less than 1 mm of resection surface along multiple foci.

Lymph Node Status: See below.

Stage: pT2cN0

Lymph nodes, bilateral pelvic, excision:

Three lymph nodes negative for metastatic carcinoma (0/3). PAS 9 SPC-A

Comments

Dr. [REDACTED] has reviewed this case and concurs.

This report has been finalized at the [REDACTED]

HPV Discrepancy		✓
Error Malignancy History		✓
Case is (Clinical) / DISQUALIFIED		
Reviewed by [REDACTED]		

4/30/13

Source: NCI Genomic Data Commons file dffb38a2-edfc-4896-adf7-4d05f7c681a9 (TCGA-HC-A6AL.2A2BA0EA-C67A-4AA6-948C-019AA6475C06.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).